EXCEPTIONAL_RESPONDERS case ER-ABXP — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d2b1569a-5129-485a-ad79-a63661818f78

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Year of birth: 1961; Vital status: Alive.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 45.2 years (16,518 days); Year of diagnosis: 2006; AJCC staging edition: 7th; Prior malignancy: no; Days to last follow up: 3,301 days (9.0 years); Days to best overall response: 377 days (1.0 years); Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Bevacizumab + Irinotecan; Days to treatment start: 341 days; Days to treatment end: 604 days (1.7 years).

Follow-up (1 entry)
- Days to follow up: 3,301 days (9.0 years); Disease response: Stable Disease; Progression or recurrence: No; Days progression-free: 3,301 days (9.0 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABXP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABXP-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
